Surgical pathology report (de-identified scan), TCGA case TCGA-06-0138, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0138-01A (Primary Tumor).

[page 1 of 2]
06-0138

PATHOLOGICAL DIAGNOSIS:

A,B. BRAIN, TEMPORAL LOBE, EXCISION: GLIOBLASTOMA.

ADDENDUM DIAGNOSIS:

BRAIN, MIB-1 PROLIFERATION INDEX: 20%.

SEE COMMENT.

Operation/Specimen: Brain tumor - permanent.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY:

A.
SPECIMEN: Brain tumor.
FIXATIVE: None.
GENERAL: Received fresh are four fragments 0.9 cm. across in aggregate. Semi-firm, tan-brown, glistening.
SECTIONS: In toto - 1 and 2.

INTRAOPERATIVE CONSULTATION, Frozen section consultation: Brain, smears: Glioblastoma.

B.
SPECIMEN: Brain tumor - permanent.
FIXATIVE: None.
GENERAL: A 2.0 x 1.5 x 0.8 cm. 1.04 gm. aggregate of few fragments of red to gray-tan soft tissue.
SECTIONS: 3,4 - all submitted.

COMMENT: The specimens consist of cerebrum diffusely infiltrated and extensively effaced by a glial neoplastic proliferation with nuclear anaplasia, mitotic figures, microvascular cellular proliferation and zones of necrosis i.e., a glioblastoma. Focally the neoplasm

[page 2 of 2]
[REDACTED]

infiltrates diffusely the cerebral cortex and is associated with microcalcification, suggestive of an oligodendroglial component. However, the bulk of the neoplasm has an astrocytic phenotype, predominantly gemistocytic.

ADDENDUM REPORT:

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, CD34, p53 and MIB-1 were performed on sections from block 4. There is gliofibrillogenesis by the neoplastic cells. Only about 3% of the neoplastic cells over express the p53 protein. With the MIB-1, a proliferation index of about 20% is determined in the more active areas. The diagnosis remains as above.

[REDACTED]

TISSUE COMMITTEE CODE: [REDACTED]

ICD9: 191.2
[REDACTED]

Source: NCI Genomic Data Commons file 5d9615b9-558a-435a-b9b5-c43fdb651e3b (TCGA-06-0138.9A7AC58B-1ECE-4196-AA88-5924F5FBE853.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).